Gene-level copy-number profile of tumor specimen MP2PRT-PAWBBC-TMP1-A from MP2PRT case MP2PRT-PAWBBC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,389 days).
Specimen MP2PRT-PAWBBC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bcc2e221-c316-4435-a7e0-4ab6318af886.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAWBBC-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/7c0e39a7-c649-4f8f-b71a-98d01fbff13d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 1,342; copy number 2: 53,428; copy number 3: 3,549.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,851,705–106,269,140, 70 genes (within-gene range 0–2) (broad region; genes not listed).
- chr21:33,915,534–33,977,691, 1 gene (within-gene range 0–2): LINC00649.
- chr21:33,967,101–34,143,034, 3 genes (within-gene range 0–2): AP000569.1, MRPS6, SLC5A3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,342. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
